Somatic mutation profile of tumor specimen TCGA-AX-A2HK-01A (aliquot TCGA-AX-A2HK-01A-11D-A17D-09) from TCGA case TCGA-AX-A2HK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.5 years (28,316 days).
Specimen TCGA-AX-A2HK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb0b0b1f-a641-4289-ad8e-05d885021414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HK-10A (Blood Derived Normal), aliquot TCGA-AX-A2HK-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b8713bf-add4-46a9-831c-6351d9e332fd

The open-access MAF lists 77 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 20, Nonsense Mutation 5, In Frame Del 3, Frame Shift Del 3, RNA 2, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASNS | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1360484422, COSV51550189; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 24/40 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.1727G>A p.G576D (on ENST00000379869 / NM_001079858.3; = p.G573D on NM_005756.4) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1417108079, COSV100492579; called by muse, mutect2
- ANKRD26 | c.3086A>G p.E1029G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101063356; called by muse, mutect2, varscan2
- CCDC88C | c.2935A>G p.I979V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV101106093; called by muse, mutect2, varscan2
- CCKBR | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201696694, COSV58101478; called by muse, mutect2, varscan2
- CCL19 | c.183G>A p.V61= | Splice Region (SNP) | VAF 22/42 reads (52%) | catalogued as rs779033374, COSV100323186; called by muse, mutect2, varscan2
- CILP2 | c.1155C>G p.C385W | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365104; called by muse, mutect2, varscan2
- CNTN5 | c.2911A>T p.K971* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV99680525; called by muse, mutect2, varscan2
- CPXM2 | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1227859179, COSV99583159; called by muse, mutect2, varscan2
- CSMD3 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV52360181; called by muse, mutect2, varscan2
- CUL4A | c.427T>C p.C143R (on ENST00000375440 / NM_001008895.4; = p.C43R on NM_003589.3) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100417491; called by muse, mutect2, varscan2
- DNAJB11 | c.225+1G>A p.X75_splice | Splice Site (SNP) | VAF 31/62 reads (50%) | catalogued as COSV99408718; called by muse, mutect2, varscan2
- DSG4 | c.196A>C p.K66Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV100356344; called by muse, mutect2, varscan2
- FNDC1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99796549; called by muse, mutect2, varscan2
- GBA2 | c.2359G>T p.E787* | Nonsense Mutation (SNP) | VAF 42/86 reads (49%) | catalogued as COSV100803478; called by muse, mutect2, varscan2
- HCN1 | c.1970C>A p.T657N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100301922; called by muse, mutect2, varscan2
- ICE1 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as COSV99665527; called by muse, mutect2
- KEL | c.1136G>C p.S379T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100787272; called by muse, mutect2, varscan2
- KTN1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV101255386; called by muse, mutect2, varscan2
- LLGL2 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99390387; called by muse, mutect2, varscan2
- LRP1B | c.10978G>C p.D3660H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101259981; called by muse, mutect2, varscan2
- MAGEB18 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100305599; called by muse, mutect2
- MROH5 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs751731711, COSV71300632; called by muse, varscan2
- N4BP2L2 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.158); catalogued as COSV99912709; called by muse, mutect2, varscan2
- NXNL1 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.855); catalogued as COSV100112043; called by muse, mutect2, varscan2
- OR51M1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs769876897, COSV60784689; called by muse, mutect2
- PCDHA3 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); catalogued as COSV100793695; called by muse, mutect2, varscan2
- PDIK1L | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.148); catalogued as COSV100957711; called by muse, mutect2, varscan2
- PHKA2 | c.2178C>A p.H726Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV101177386; called by muse, mutect2, varscan2
- PLPP6 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.469); catalogued as COSV99795100; called by muse, mutect2, varscan2
- POM121L12 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.752); catalogued as COSV101374970; called by muse, mutect2, varscan2
- PTPRA | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53789196, COSV99400507; called by muse, mutect2, varscan2
- RAPGEF1 | c.2042C>T p.T681M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs767153483, COSV64702066; called by muse, mutect2, varscan2
- REV3L | c.2325G>C p.R775S | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100725618; called by muse, mutect2, varscan2
- SCUBE1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99298572; called by muse, mutect2, varscan2
- SIM1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53496412; called by muse, mutect2, varscan2
- SIRPB1 | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 31/188 reads (16%) | catalogued as rs777118023, COSV99498545; called by muse, mutect2, varscan2
- SOX7 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.442); catalogued as rs1250612484, COSV58731775; called by muse, mutect2, varscan2
- THBS2 | c.1692C>A p.C564* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100828034; called by muse, mutect2, varscan2
- TNXB | c.7183G>A p.V2395I (on ENST00000647633; = p.V2148I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV100926577; called by muse, mutect2, varscan2
- TP53 | c.497_498insT p.Q167Tfs*14 | Frame Shift Ins (INS) | VAF 34/47 reads (72%) | catalogued as COSV53059983, COSV53125131, COSV99444099; called by mutect2, pindel, varscan2
- TRIM5 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000636; called by muse, mutect2, varscan2
- TTC30B | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101282807; called by muse, mutect2, varscan2
- UBE4A | c.1828C>G p.L610V (on ENST00000252108 / NM_001204077.2; = p.L617V on NM_004788.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.111); catalogued as COSV99348530; called by muse, mutect2, varscan2
- USF1 | c.625C>A p.R209S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99231251; called by muse, mutect2
- ZCCHC12 | c.990C>A p.N330K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as COSV100038642; called by muse, mutect2, varscan2
- ZNF292 | c.7933T>G p.C2645G | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100371022; called by muse, mutect2, varscan2
- ZNF665 | c.1217C>G p.S406* (on ENST00000600412; = p.S471* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/35 reads (71%) | catalogued as COSV101128728; called by muse, mutect2, varscan2
- ABRAXAS2 | c.651_654del p.E218Kfs*23 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- CEP250 | c.3227_3228del p.S1076Yfs*40 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | called by pindel, varscan2
- ITIH2 | c.1163_1165del p.I388del | In Frame Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1354_1374del p.Y452_E458del (on ENST00000521381 / NM_181523.3; = p.Y182_E188del on NM_181504.4) | In Frame Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- TGFB1I1 | c.1018_1023del p.Q340_L341del (on ENST00000394863 / NM_001042454.3; = p.Q323_L324del on NM_015927.4) | In Frame Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- TNXB | c.4734del p.L1579Ffs*47 (on ENST00000647633; = p.L1332Ffs*47 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.3048C>T p.R1016= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100068557; called by muse, mutect2
- COL14A1 | c.4641T>C p.D1547= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99920414; called by muse, mutect2, varscan2
- CRISPLD1 | c.48C>T p.F16= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV100082362; called by muse, mutect2, varscan2
- DDX60 | c.879A>G p.Q293= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as rs768396338, COSV101190625; called by muse, mutect2, varscan2
- DSG4 | c.195G>A p.S65= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1011420811, COSV100356338, COSV57389068; called by muse, mutect2, varscan2
- F13B | c.435C>A p.T145= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1433199892, COSV66372566; called by muse, mutect2
- FAT4 | c.12768C>T p.S4256= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1006074076, COSV100629860; called by muse, mutect2, varscan2
- FRYL | c.8721T>C p.S2907= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99977907; called by muse, mutect2, varscan2
- GPAT3 | c.1011C>T p.F337= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs764983189, COSV52356664; called by muse, mutect2, varscan2
- KCNH6 | c.2034C>G p.T678= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV100121221; called by muse, mutect2, varscan2
- KIF2B | c.312G>A p.S104= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs543663752, COSV52129067, COSV52133640; called by muse, mutect2
- NLRP8 | c.765C>T p.S255= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99405841; called by muse, mutect2
- PRDM9 | c.873C>T p.Y291= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as rs554907629; called by muse, mutect2
- RNF165 | c.118C>T p.L40= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV99492017; called by muse, mutect2, varscan2
- STUB1 | c.459G>T p.R153= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99555956; called by muse, mutect2, varscan2
- TENM4 | c.6279C>T p.S2093= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV99578287; called by muse, mutect2, varscan2
- TTN | c.92133T>A p.R30711= (on ENST00000591111; = p.R23287= on NM_003319.4) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100626635; called by muse, mutect2
- TTN | c.88821A>T p.T29607= (on ENST00000591111; = p.T22183= on NM_003319.4) | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100626636; called by muse, mutect2, varscan2
- VSIG4 | c.678G>C p.V226= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101038273; called by muse, mutect2, varscan2
- ZFPL1 | c.294C>G p.P98= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99298002; called by muse, mutect2, varscan2
- LINC02145 | n.361T>C | RNA (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- SNORD116-2 | n.5C>G | RNA (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
